Gene-level copy-number profile of tumor specimen TCGA-58-A46L-01A from TCGA case TCGA-58-A46L, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 73.1 years (26,685 days).
Specimen TCGA-58-A46L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.ee9882b2-4283-423c-8d15-21e6fbae1d30.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-58-A46L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0b51015e-0276-4fd6-b7aa-c7c288f7d8c6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 130; copy number 1: 18,841; copy number 2: 31,018; copy number 3: 5,646; copy number 4: 2,619; copy number 5: 775; copy number 6: 368; copy number 7: 118; copy number 8: 37; copy number 9: 45; copy number 10: 3; copy number 11: 39; copy number 12: 171; copy number 14: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-58-A46L-01A-11D-A24C-01): tumor purity 0.58, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 130 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:50,669,989–50,672,048, 1 gene: LINC02019.
- chr3:50,675,080–50,788,285, 4 genes: MIR4787, PPIAP69, AC126120.1, ZNF652P1.
- chr4:160,521,829–160,586,817, 2 genes: AC093853.1, LINC02477.
- chr7:127,652,194–128,092,609, 5 genes (within-gene range 0–2): SND1, AC006529.1, SND1-IT1, LRRC4, MIR593.
- chr9:20,999,509–27,944,497, 106 genes (broad region; genes not listed).
- chr9:28,148,211–28,149,236, 1 gene: AL451124.1.
- chr16:56,989,485–57,240,469, 10 genes (within-gene range 0–1): NLRC5, AC023825.1, AC023825.2, AC009090.2, CPNE2, AC009090.4, AC009090.5, PSME3IP1, AC009090.6, RSPRY1.
- chr16:57,245,832–57,246,396, 1 gene: AC009090.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,559 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:180,509,380–182,090,112, 26 genes, copy number 6: OVAAL, Y_RNA, XPR1, U6, LINC02816, KIAA1614, AL162431.1, KIAA1614-AS1, AL162431.2, AL162431.3, STX6, MR1, IER5, LINC01732, AL358393.1, LINC01699, CACNA1E, Metazoa_SRP, RNA5SP70, AL161734.2, AL161734.1, RN7SKP229, AL391477.1, ZNF648, AL355482.1, AL355482.2.
- chr1:182,127,297–182,128,682, 1 gene, copy number 6: AL390856.1.
- chr1:189,035,961–189,133,292, 2 genes, copy number 5: CLPTM1LP1, GAPDHP75.
- chr1:224,297,646–226,833,906, 57 genes, copy number 5–12: AC092809.1, RNU6-1008P, CNIH4, WDR26, MIR4742, CNIH3, AKR1B1P1, CNIH3-AS2, DNAJB6P6, AL596330.1, CNIH3-AS1, LINC02813, AL391811.1, DNAH14, LBR, LINC02765, AC092811.1, ENAH, AC099066.2, AC099066.1, RNU6-1304P, SRP9, AC099066.3, EPHX1, AL591895.1, TMEM63A, LEFTY1, AL117348.2, PYCR2, MIR6741, AL117348.1, LEFTY2, NDUFA3P3, SDE2, AL512343.2, H3-3A, LINC01703, AL512343.1, ACBD3, ACBD3-AS1, AL592045.1, MIXL1, LIN9, YBX1P9, AL359742.1, PARP1, AL359704.1, RPS3AP7, RN7SKP165, CDKN2AIPNLP1, AL359704.2, STUM, ITPKB, ITPKB-IT1, ITPKB-AS1, RPS27P5, AL359732.1.
- chr1:247,099,962–247,210,856, 11 genes, copy number 5: ZNF669, AL627095.2, C1orf229, FGFR3P6, ZNF124, AL390728.3, AL390728.2, AL390728.6, AL390728.4, MIR3916, RNA5SP82.
- chr3:174,438,573–175,810,548, 1 gene, copy number 6 (within-gene range 4–6): NAALADL2.
- chr3:175,059,361–198,222,513, 497 genes, copy number 5–6 (broad region; genes not listed).
- chr4:53,377,839–57,855,271, 97 genes, copy number 9–12 (within-gene range 1–12) (broad region; genes not listed).
- chr4:58,780,626–60,796,103, 15 genes, copy number 6–10: AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1, LINC02496, AC105420.1.
- chr5:10,971,836–23,305,143, 139 genes, copy number 5–11 (broad region; genes not listed).
- chr7:21,900,899–23,564,261, 35 genes, copy number 7–9: CDCA7L, RAPGEF5, RNA5SP227, STEAP1B, EEF1A1P6, AC002480.1, AC002480.2, IL6-AS1, IL6, MTCYBP42, AC073072.1, TOMM7, AC005682.2, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A, KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1.
- chr7:52,891,837–56,882,146, 105 genes, copy number 12–14 (broad region; genes not listed).
- chr9:28,863,626–28,888,955, 2 genes, copy number 6: MIR876, MIR873.
- chr12:68,272,443–68,332,381, 1 gene, copy number 8 (within-gene range 2–8): MDM1.
- chr19:14,254,189–14,293,205, 1 gene, copy number 5 (within-gene range 4–5): AC011509.2.
- chr19:14,305,458–16,817,963, 139 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:27,638,483–28,125,430, 15 genes, copy number 5: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1.
- chr19:28,949,437–39,694,577, 415 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,454. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
